Somatic mutation profile of tumor specimen TCGA-AZ-6608-01A (aliquot TCGA-AZ-6608-01A-11D-1835-10) from TCGA case TCGA-AZ-6608, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 55.0 years (20,094 days).
Specimen TCGA-AZ-6608-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8eb0f90-b14b-45b3-b8e6-a266f4191a80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-6608-11A (Solid Tissue Normal), aliquot TCGA-AZ-6608-11A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d9f6681-45aa-4654-8a0f-c215694ca004

The open-access MAF lists 159 somatic variants for this specimen: 123 protein-altering or splice-affecting, 36 silent.
By variant classification: Missense Mutation 95, Silent 36, Nonsense Mutation 9, Splice Site 8, Frame Shift Ins 5, Splice Region 3, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 77/192 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455dup p.P153Afs*28 | Frame Shift Ins (INS) | VAF 9/21 reads (43%) | catalogued as rs730882019, COSV53468298, COSV99394349; ClinVar: pathogenic; called by mutect2, pindel
- ABCA13 | c.6620A>T p.N2207I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV101330125; called by muse, mutect2, varscan2
- ABCD2 | c.799A>T p.T267S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.951); catalogued as COSV100429677; called by muse, mutect2, varscan2
- ADCY8 | c.3214G>T p.E1072* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV53922880, COSV99653381; called by muse, mutect2, varscan2
- AGBL4 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs771499735, COSV61893448; called by muse, mutect2, varscan2
- APC | c.556A>T p.R186* | Nonsense Mutation (SNP) | VAF 69/126 reads (55%) | catalogued as CD971982, COSV99969101; called by muse, mutect2, varscan2
- APC | c.3991A>T p.R1331* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as CD1110520, CM083581, COSV57347637; called by muse, mutect2, varscan2
- ARFGEF3 | c.1883C>T p.S628L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV99292517, COSV99294225; called by mutect2, varscan2
- ARR3 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs746178806, COSV52104143; called by muse, mutect2, varscan2
- ASPM | c.7205G>C p.R2402T | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.688); catalogued as rs755628713, COSV54135466; called by muse, mutect2, varscan2
- ASTN2 | c.2133T>A p.C711* (on ENST00000313400 / NM_001365069.1; = p.C660* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV100529144; called by muse, mutect2, varscan2
- ATG2B | c.2559T>A p.N853K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.172); catalogued as COSV100738133; called by muse, mutect2, varscan2
- ATG4B | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as COSV100728731; called by muse, mutect2, varscan2
- ATP10B | c.2667C>G p.I889M | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100513808, COSV100515452; called by muse, mutect2, varscan2
- ATP2A2 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100428793; called by muse, mutect2, varscan2
- ATR | c.3358-2A>T p.X1120_splice | Splice Site (SNP) | VAF 182/405 reads (45%) | catalogued as COSV100638428; called by muse, mutect2, varscan2
- B3GNTL1 | c.505-2A>T p.X169_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV57954087; called by muse, mutect2, varscan2
- BCORL1 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV54391360; called by muse, mutect2, varscan2
- BTBD11 | c.2024A>G p.K675R (on ENST00000280758 / NM_001018072.2; = p.K212R on NM_001017523.2) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.446); catalogued as COSV99776505; called by muse, mutect2, varscan2
- CCNL1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs1560196531, COSV55820572; called by mutect2, varscan2
- CELA3B | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138341071; called by muse, mutect2, varscan2
- CFH | c.58+1G>A p.X20_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV100661549; called by muse, mutect2, varscan2
- CLCN4 | c.147C>T p.I49= | Splice Region (SNP) | VAF 55/124 reads (44%) | catalogued as COSV101073944; called by muse, mutect2, varscan2
- CLEC2B | c.117G>C p.W39C | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99947039; called by muse, mutect2, varscan2
- COL14A1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as rs759810359, COSV52850420; called by muse, mutect2, varscan2
- COL6A3 | c.5726A>C p.E1909A | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV99800023; called by muse, mutect2, varscan2
- CSMD1 | c.1009T>A p.L337M | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); catalogued as COSV101222937; called by muse, mutect2, varscan2
- CYB561 | c.386T>A p.F129Y | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV100669147; called by muse, mutect2, varscan2
- DCC | c.1963A>T p.I655F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100501837; called by muse, mutect2, varscan2
- DGKB | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.921); catalogued as rs751564836, COSV51828948; called by muse, mutect2, varscan2
- DLGAP2 | c.2446A>T p.S816C | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV101422427; called by muse, mutect2, varscan2
- DOK6 | c.770T>C p.L257S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs981732069, COSV101234753; called by muse, varscan2
- ELL | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99443537; called by muse, mutect2, varscan2
- FAM47B | c.188A>C p.Q63P | Missense Mutation (SNP) | VAF 147/298 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100264491; called by muse, varscan2
- FASTKD2 | c.265G>C p.G89R | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.057); catalogued as COSV52700261; called by muse, mutect2, varscan2
- FASTKD2 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1317181507, COSV52700273; called by muse, mutect2, varscan2
- FLNC | c.5573A>T p.N1858I | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100368455, COSV57965607; called by muse, mutect2, varscan2
- FURIN | c.1766C>T p.T589I | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV99184739; called by muse, mutect2, varscan2
- GALNT17 | c.1329T>A p.C443* | Nonsense Mutation (SNP) | VAF 30/47 reads (64%) | catalogued as COSV100354999; called by muse, mutect2, varscan2
- GUCY2F | c.438T>G p.I146M | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV99485383; called by muse, mutect2, varscan2
- IFNA14 | c.550A>T p.R184* | Nonsense Mutation (SNP) | VAF 48/134 reads (36%) | catalogued as COSV101207329; called by muse, mutect2, varscan2
- ITGA11 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100241943; called by muse, varscan2
- KIF15 | c.1528G>T p.V510F | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as COSV100393082; called by muse, mutect2, varscan2
- KLF5 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104427591, COSV66614665; called by muse, mutect2, varscan2
- KLHL11 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV59862210; called by muse, mutect2, varscan2
- LFNG | c.670T>C p.Y224H (on ENST00000222725 / NM_001040167.2; = p.Y95H on NM_002304.2) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99761875; called by muse, mutect2, varscan2
- LRP1B | c.11132T>C p.V3711A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs111336992, COSV101258631; called by mutect2, varscan2
- LYST | c.10704G>C p.V3568= | Splice Region (SNP) | VAF 32/85 reads (38%) | catalogued as COSV101089989; called by muse, mutect2, varscan2
- MAP7D2 | c.618A>T p.L206F | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101107471; called by muse, mutect2, varscan2
- MARK2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1225368156, COSV59286509; called by muse, mutect2, varscan2
- MBD6 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as rs1015636367, COSV100851745; called by muse, mutect2, varscan2
- MPP7 | c.1622A>G p.K541R | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV100517682; called by muse, mutect2, varscan2
- MYH2 | c.5044C>T p.R1682C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568249919, COSV104393337, COSV55432102, COSV99819620; called by muse, mutect2, varscan2
- MYPN | c.2756G>A p.R919H | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs193022869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOD1 | c.1361A>T p.H454L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99768317; called by muse, mutect2, varscan2
- NR1I2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1384110705, COSV100561652; called by muse, mutect2, varscan2
- NR4A3 | c.1313A>G p.Y438C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461215273, COSV58248420; called by muse, mutect2, varscan2
- NXF3 | c.1336-2A>T p.X446_splice | Splice Site (SNP) | VAF 87/203 reads (43%) | catalogued as COSV67704553; called by muse, mutect2, varscan2
- OBSCN | c.18325C>T p.R6109W | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs542213579, COSV99482092; called by muse, mutect2, varscan2
- OR1C1 | c.348T>A p.C116* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV101376257; called by muse, mutect2, varscan2
- OR2B11 | c.110T>A p.L37Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100276414; called by muse, mutect2, varscan2
- OR52N4 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs1319052476, COSV100421725; called by muse, mutect2, varscan2
- PARP4 | c.3553G>C p.E1185Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67962435; called by muse, mutect2
- PCDHB13 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 3/204 reads (1%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs782093598; called by muse, mutect2
- PCDHB3 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as COSV99165940; called by muse, mutect2, varscan2
- PDE11A | c.484A>G p.S162G | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV99613865; called by muse, mutect2, varscan2
- PDE1C | c.852-2A>C p.X284_splice | Splice Site (SNP) | VAF 9/87 reads (10%) | catalogued as COSV100373220; called by muse, mutect2
- PEX19 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100926969; called by muse, mutect2, varscan2
- PHF3 | c.2988A>T p.L996F | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013697; called by muse, mutect2, varscan2
- PI4K2B | c.481A>T p.K161* | Nonsense Mutation (SNP) | VAF 51/89 reads (57%) | catalogued as COSV99335584; called by muse, mutect2, varscan2
- PKHD1L1 | c.4709A>G p.N1570S | Missense Mutation (SNP) | VAF 71/100 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101006611; called by muse, varscan2
- POLR2B | c.1778A>T p.Q593L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.297); catalogued as COSV100108230; called by muse, mutect2, varscan2
- PPP1R12A | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99700624; called by muse, mutect2, varscan2
- PPP1R3A | c.2585T>A p.L862Q | Missense Mutation (SNP) | VAF 87/145 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0.036); catalogued as COSV99493590; called by muse, mutect2, varscan2
- PROM1 | c.2176T>A p.F726I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV101477113; called by muse, mutect2, varscan2
- RAB1A | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99561120; called by muse, mutect2, varscan2
- RASAL3 | c.1710C>G p.I570M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV100640320; called by mutect2, varscan2
- RASGRP3 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 97/166 reads (58%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as rs756271456, COSV67825239; called by muse, mutect2, varscan2
- RELL1 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs200794467; called by muse, mutect2, varscan2
- RNF214 | c.680A>G p.D227G | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.914); catalogued as COSV100326842; called by muse, mutect2
- ROBO4 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs749338809, COSV60624136; called by muse, mutect2, varscan2
- RTTN | c.1188A>T p.T396= | Splice Region (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99733252; called by muse, mutect2, varscan2
- RYR2 | c.2023T>A p.Y675N | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100772039; called by muse, mutect2, varscan2
- SEMA4A | c.160A>T p.S54C | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV61774114; called by muse, mutect2, varscan2
- SLC2A10 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs558025597, COSV100826391; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC44A5 | c.508A>T p.T170S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100902299; called by muse, mutect2, varscan2
- SMTNL1 | c.1349G>T p.G450V (on ENST00000399154; = p.G487V on NM_001105565.2) | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54703964; called by muse, mutect2, varscan2
- SNED1 | c.1958A>C p.H653P | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100123102; called by muse, varscan2
- SNX2 | c.240A>T p.E80D | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); catalogued as COSV101075788; called by muse, mutect2, varscan2
- SOHLH2 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs142901524; called by muse, mutect2, varscan2
- SPINK5 | c.881T>G p.V294G | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV99807095; called by muse, mutect2, varscan2
- SRRM1 | c.617A>C p.K206T | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.16); catalogued as COSV100104940; called by muse, mutect2, varscan2
- STARD8 | c.946T>A p.W316R | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV52933006; called by muse, mutect2, varscan2
- STC2 | c.715C>A p.H239N | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV99438558; called by mutect2, varscan2
- STS | c.1082-2A>C p.X361_splice | Splice Site (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99481510; called by muse, mutect2, varscan2
- TASOR | c.4136-1G>C p.X1379_splice (on ENST00000355628 / NM_001365636.2; = p.X1003_splice on NM_015224.3) | Splice Site (SNP) | VAF 55/134 reads (41%) | catalogued as COSV58309518; called by muse, mutect2, varscan2
- TDRKH | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 73/118 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100917996; called by muse, mutect2, varscan2
- THBS1 | c.1763A>T p.D588V | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99528211; called by muse, mutect2, varscan2
- TMC2 | c.443T>A p.L148Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.642); catalogued as COSV100727787; called by muse, mutect2, varscan2
- TMEM198 | c.1024T>A p.Y342N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99525217; called by muse, mutect2, varscan2
- TMEM62 | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99543780; called by muse, mutect2, varscan2
- TRHDE | c.2427A>T p.Q809H | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV99671753; called by muse, mutect2, varscan2
- WASHC5 | c.2482A>T p.I828F | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100572965; called by muse, mutect2, varscan2
- ZFAND2A | c.283A>T p.I95F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100335954; called by muse, mutect2, varscan2
- ZFP82 | c.842C>G p.P281R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101089227; called by muse, mutect2, varscan2
- ZFYVE26 | c.4060C>T p.R1354W | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs370890942; called by muse, mutect2, varscan2
- ZNF251 | c.1146T>A p.C382* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99478706; called by muse, mutect2, varscan2
- ZNF28 | c.508A>C p.N170H | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV60424838, COSV60425409; called by muse, mutect2, varscan2
- ZNF492 | c.1187A>T p.E396V | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101514031; called by muse, mutect2, varscan2
- ZNF831 | c.3266T>C p.L1089P | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100926150; called by muse, mutect2, varscan2
- ZNF98 | c.1310A>T p.E437V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV100757556; called by mutect2, varscan2
- ZSCAN1 | c.794T>G p.L265R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56608817; called by muse, mutect2
- ADAMTS2 | c.1790dup p.R598Pfs*24 | Frame Shift Ins (INS) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- ALPK2 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP20 | c.186_188+1del p.X62_splice | Splice Site (DEL) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- CCDC180 | c.3028del p.S1010Lfs*19 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- DNAJC4 | c.121dup p.V41Gfs*8 | Frame Shift Ins (INS) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- GORASP1 | c.207_227del p.E70_T76del | In Frame Del (DEL) | VAF 50/133 reads (38%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.1745dup p.I583Dfs*18 | Frame Shift Ins (INS) | VAF 141/372 reads (38%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.3190_3202del p.C1064Ifs*31 (on ENST00000357337; = p.C1102Ifs*31 on NM_015057.5) | Frame Shift Del (DEL) | VAF 18/209 reads (9%) | called by mutect2, pindel
- PCDHB9 | c.1008A>T p.K336N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WNK1 | c.75dup p.K26Qfs*51 | Frame Shift Ins (INS) | VAF 34/95 reads (36%) | called by mutect2, pindel, varscan2
- ABCA9 | c.3564T>G p.P1188= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV100383329; called by muse, mutect2, varscan2
- ALOX15B | c.1371T>C p.P457= | Silent (SNP) | VAF 34/44 reads (77%) | catalogued as rs1567972940, COSV101205664; called by muse, mutect2, varscan2
- C11orf65 | c.99A>G p.Q33= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV67598706; called by muse, mutect2, varscan2
- CCDC120 | c.1635T>A p.A545= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100896755; called by muse, mutect2, varscan2
- CFAP47 | c.2817C>T p.N939= | Silent (SNP) | VAF 66/161 reads (41%) | catalogued as rs377100055, COSV99935560; called by muse, mutect2, varscan2
- CGNL1 | c.2124A>T p.S708= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99848773; called by muse, mutect2, varscan2
- CMA1 | c.84C>T p.C28= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99157581; called by muse, mutect2, varscan2
- CSMD3 | c.447T>A p.S149= | Silent (SNP) | VAF 58/89 reads (65%) | catalogued as COSV99841693; called by muse, mutect2, varscan2
- DHX8 | c.1647T>A p.S549= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99292471; called by muse, mutect2, varscan2
- DNAJC13 | c.717A>T p.V239= | Silent (SNP) | VAF 57/116 reads (49%) | catalogued as COSV99607745; called by muse, mutect2, varscan2
- DSE | c.1275T>A p.R425= | Silent (SNP) | VAF 56/82 reads (68%) | catalogued as COSV100528693, COSV59067095; called by muse, varscan2
- FAM131A | c.477C>T p.G159= (on ENST00000310585; = p.G190= on NM_144635.5) | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as rs571174963, COSV55599064; called by muse, mutect2, varscan2
- FAM171B | c.1962A>T p.S654= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV100488844; called by muse, mutect2, varscan2
- FOXD4L6 | c.1185G>A p.A395= | Silent (SNP) | VAF 16/86 reads (19%) | called by mutect2, varscan2
- FSD1 | c.1233C>A p.V411= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99696927; called by muse, mutect2, varscan2
- HERPUD2 | c.163A>C p.R55= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV100258042; called by muse, mutect2
- JAK3 | c.1764C>T p.H588= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs201482851, COSV101512985; called by muse, mutect2, varscan2
- MAGED2 | c.291T>A p.A97= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as COSV99514676; called by muse, mutect2, varscan2
- MRGPRX1 | c.891C>T p.D297= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs762771386, COSV57108025; called by muse, mutect2, varscan2
- NEB | c.14787T>A p.T4929= | Silent (SNP) | VAF 46/80 reads (58%) | catalogued as COSV51460588; called by muse, mutect2, varscan2
- PAK5 | c.42G>A p.P14= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs370805526, COSV62041063; called by muse, mutect2, varscan2
- PANK2 | c.1710G>A p.P570= (on ENST00000316562 / NM_153638.3; = p.P279= on NM_024960.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs762044608, COSV57256331; called by muse, mutect2, varscan2
- PCDHGA10 | c.2244C>T p.D748= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as COSV54006574; called by muse, mutect2, varscan2
- PDP1 | c.297A>T p.P99= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV99892679; called by muse, mutect2, varscan2
- PSG6 | c.579G>A p.Q193= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs1054549643, COSV51838050; called by muse, mutect2, varscan2
- RBFOX1 | c.786C>T p.T262= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs755253534, COSV100302663, COSV60958161; called by muse, mutect2
- SAMD9L | c.2299T>C p.L767= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV100560982; called by muse, mutect2, varscan2
- SLC2A5 | c.1077C>A p.L359= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV101072678; called by muse, mutect2, varscan2
- STEAP3 | c.1425G>A p.L475= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV100713431; called by muse, mutect2, varscan2
- TBX5 | c.432C>T p.T144= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as rs146038442, CD991892, COSV100090590; called by muse, mutect2, varscan2
- TPP2 | c.3684C>T p.T1228= | Silent (SNP) | VAF 51/85 reads (60%) | catalogued as COSV101060353, COSV101060360; called by muse, mutect2, varscan2
- TRHDE | c.12C>T p.D4= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99671752; called by muse, mutect2, varscan2
- TRIM50 | c.1314G>A p.P438= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs781946593, COSV53093783; called by muse, mutect2, varscan2
- TTN | c.64818G>A p.P21606= (on ENST00000591111; = p.P14182= on NM_003319.4) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs566393354, COSV60283478; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.1338A>T p.V446= | Silent (SNP) | VAF 47/76 reads (62%) | catalogued as COSV100622423; called by muse, mutect2, varscan2
- WASF1 | c.1044T>G p.P348= | Silent (SNP) | VAF 20/26 reads (77%) | catalogued as COSV63936183; called by muse, mutect2
